Gene-level copy-number profile of tumor specimen TCGA-CF-A7I0-01A from TCGA case TCGA-CF-A7I0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 54.9 years (20,059 days).
Specimen TCGA-CF-A7I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.665122ab-75d7-48bc-9090-c8cde818775b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A7I0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56043bd6-fe38-48b7-9e76-cc67bbd230da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,746; copy number 2: 48,413; copy number 3: 201; copy number 4: 186; copy number 5: 135; copy number 6: 111; copy number 32: 20; copy number 33: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A7I0-01A-22D-A34T-01): tumor purity 0.68, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 273 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:63,844,700–64,162,217, 1 gene, copy number 5 (within-gene range 1–5): SRGAP1.
- chr12:63,887,379–64,147,857, 6 genes, copy number 5: AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr12:64,507,001–64,697,564, 1 gene, copy number 6 (within-gene range 1–6): RASSF3.
- chr12:64,575,665–65,121,305, 19 genes, copy number 6 (within-gene range 4–6): SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P.
- chr12:67,265,842–67,590,771, 7 genes, copy number 33 (within-gene range 4–33): GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408.
- chr12:68,957,377–69,738,574, 20 genes, copy number 32: PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1.
- chr12:113,789,542–122,422,632, 219 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,365. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
